Surgical pathology report (de-identified scan), TCGA case TCGA-46-6025, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site St. Joseph's Medical Center (MD), specimen TCGA-46-6025-01A (Primary Tumor).

[page 1 of 5]
PRIORITY: FROZEN SEC

TCGA-46-6025

SURGICAL PROCEDURES:

LUNG-LOBECTOMY, RESECTION, REGIONAL LYMPH

CLINICAL HISTORY

PRE-OPERATIVE DIAGNOSIS: SQUAMOUS CELL CARCINOMA RIGHT LOWER LUNG

GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "right bilobectomy, middle and lower lobes" and consists of two lobes of lung consistent with middle and lower lobes, right side, weighing 520 grams. The middle lobe measures 8 x 7 x 4 cm in dimension. The lower lobe measures 17 x 14 x 6 cm in dimension. The pleural surfaces are purple tan and reticulated with deposits of black carbon pigment. The lower lobe is interrupted by a firm palpable and puckered sub-pleural area measuring 6 x 4 x 3 cm in dimension with the pleural puckering approaching to within 4 cm of the bronchial margin of resection. At the hilum, the bronchial margin of resection measures 2 cm in diameter. A single well defined vessel is noted measuring 1 cm in diameter. Four well defined gray black nodules are seen ranging 0.6 cm to 0.8 cm in diameter. The pleural surface at the level of the puckering will be marked with blue dye. Serial sectioning of the lower lobe reveals a firm yellow tan lesion measuring 5.5 x 3.5 x 3 cm with a central necrotic cavity measuring 3 cm in greatest dimension. The tumor approaches to within 3 cm of the bronchial margin of resection and directly underlies the puckered area of pleura. Further sectioning reveals a second possible lesion and/or involved lymph node directly underlying the bronchial margin of resection measuring 3 x 2 x 1.7 cm in dimension. Bronchial mucosal involvement is not identified. Sectioning of the middle lobe is unremarkable. Sectioning of the lower lobe between the two lesions reveals additional identified lymph nodes ranging 0.6 cm to 1.1 cm in dimension. The peripheral base of the specimen exhibits a slight granular pattern.

[page 2 of 5]
GROSS DESCRIPTION

(Continued)

Sectioning does not reveal a defined lesion. Sectioning of the middle lobe is unremarkable. Representative sections are submitted; 19 (12) and 1 (1) labeled "FSP" for frozen section:

Cassette 1:	Vessel margin of resection.
Cassette 2:	Hilar lymph nodes.
Cassette 3:	Sub-hilar lymph nodes.
Cassettes 4-6:	Tumor pleural mass.
Cassettes 7-9:	Hilar tumor or lymph node.
Cassette 10:	Peripheral lower lobe nodularity.
Cassettes 11 & 12:	Representative uninvolved pulmonary parenchyma as taken from the middle lobe.
Cassette "FSP":	Frozen section.

FROZEN SECTION DIAGNOSIS: Bronchial margin negative for tumor.

NOTE: Additional tissue has been submitted for TCGA.

B. The specimen is submitted fresh as "9R" and consists of two pink gray to pink yellow nodular segments of tissue measuring 1.5 cm each in greatest dimension. One segment will be marked with black dye for differentiation. Each nodule is bisected and the specimen is submitted in toto; 4 (2) "1" and "2".

C. The specimen is submitted fresh as "11R" and consists of five red brown to black nodules ranging 0.3 cm to 0.6 cm in dimension. The specimen is wrapped in tissue paper and submitted in toto; 5 (2) "1" and "2".

D. The specimen is submitted fresh as "posterior 11R" and consists of six red brown to black nodules ranging 0.3 cm to 1.2 cm in dimension. The largest is elongated. The specimen is wrapped in tissue paper and submitted in toto; 6 (1).

E. The specimen is submitted fresh as "10R anterior" and consists of three red black elongated tissue fragments ranging 0.6 cm to 1.3 cm in dimension; submitted in toto; 3 (1).

F. The specimen is submitted fresh as "right apical bleb" and consists of a wedge shaped segment of pulmonary tissue measuring 3.5 x 1.8 x 0.7 cm in dimension. The margin is sealed with metallic staples. The pleural surface is red tan interrupted by a soft air filled area consistent with a bleb measuring 0.7 cm in dimension. The staple line is removed and the surgical margin marked with black dye. Sectioning of the specimen is further unremarkable. The specimen is submitted in toto; 4 (2) "1" and

[page 3 of 5]
GROSS DESCRIPTION

(Continued)

G. The specimen is submitted fresh as "4R" and consists of ten pink yellow lobulated segments of adipose tissue and apparent lymphoid tissue ranging 0.3 cm to 2 cm in dimension. The specimen is wrapped in tissue paper and submitted in toto; 10 (3) "1" through "3".

H. The specimen is submitted fresh as "fifth rib right" and consists of a segment of hard pink coarse bone consistent with rib measuring 1.8 x 1.2 x 0.8 cm in dimension. Sectioning is unremarkable. A representative section is submitted; 1 (1) for decalcification.

I. The specimen is submitted fresh as "sixth rib right" and consists of a segment of hard pink porous bone consistent with rib measuring 2 x 1 x 0.9 cm in dimension. Representative sections are submitted; 2 (1) for decalcification.

J. The specimen is submitted fresh as "level 7" and consists of multiple soft deep red to black nodular and irregular fragments of tissue ranging 0.4 cm to 1.7 cm in dimension. The specimen is submitted in toto; multiple (3) "1" through "3".

FINAL DIAGNOSIS

A. LUNG, RIGHT MIDDLE AND LOWER LOBES (BILOBECTOMY):

- MODERATE TO POORLY DIFFERENTIATED SQUAMOUS CARCINOMA OF THE RIGHT LOWER LOBE (5.5 CM).
- TUMOR IS CONFINED TO PLEURAL PARENCHYMA, CLOSELY APPROACHING BUT NOT INVOLVING VISCERAL PLEURA (ELASTIN).
- METASTATIC SQUAMOUS CARCINOMA IS PRESENT IN ONE LYMPH NODE AGGREGATE OF FOUR HILAR LYMPH NODES REMOVED FROM SPECIMEN.
- METASTATIC TUMOR FOCUS MEASURES 3 CM IN DIMENSION WITH EXTRANODAL EXTENSION, AND ENCROACHES BUT DOES NOT INVADE BRONCHIAL ARTERY.
- ALL SURGICAL MARGINS INCLUDING BRONCHIAL, VASCULAR, AND PLEURAL ARE NEGATIVE FOR TUMOR.
- NON-NEOPLASTIC LUNG PARENCHYMA PERIPHERAL TO LARGE TUMOR MASS SHOWS INTERSTITIAL FIBROSIS AND REACTIVE CHANGES. PROXIMAL TO TUMOR MASS, NON-NEOPLASTIC LUNG PARENCHYMA SHOWS EMPHYSEMATOUS CHANGES, CONGESTION AND INTERSTITIAL FIBROSIS.
- PATHOLOGIC STAGE: pT2b N1 MX

B. LYMPH NODES, 9R: TWO ANTHRACOTIC LYMPH NODES, NEGATIVE FOR TUMOR.

C. LYMPH NODES, 11R: FIVE ANTHRACOTIC LYMPH NODES, NEGATIVE FOR TUMOR.

D. LYMPH NODES, POSTERIOR 11R: SIX LYMPH NODES, NEGATIVE FOR TUMOR.

[page 4 of 5]
FINAL DIAGNOSIS

(Continued)

- E. LYMPH NODES, 10R ANTERIOR: THREE LYMPH NODES, NEGATIVE FOR TUMOR.
- F. LUNG, RIGHT APEX (EXCISION): BENIGN LUNG PARENCHYMA WITH FIBROSIS AND APICAL BLEB FORMATION, NEGATIVE FOR TUMOR.
- G. LYMPH NODES, 4R: SIX FRAGMENTS OF LYMPH NODE, NEGATIVE FOR TUMOR.
- H. RIGHT 5TH RIB (THORACOTOMY): HISTOLOGICALLY UNREMARKABLE RIB, NEGATIVE FOR TUMOR.
- I. RIGHT 6TH RIB (THORACOTOMY): HISTOLOGICALLY UNREMARKABLE SEGMENT OF RIB, NEGATIVE FOR TUMOR.
- J. LYMPH NODES, LEVEL 7: MULTIPLE LYMPH NODES, NEGATIVE FOR TUMOR.

SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: BILOBECTOMY
SPECIMEN INTEGRITY: INTACT
LATERALITY: RIGHT
TUMOR SITE: LOWER LOBE
TUMOR SIZE: 5.5 CM
TUMOR FOCALITY: UNIFOCAAL WITH METASTASIS
HISTOLOGIC TYPE: SQUAMOUS CELL
HISTOLOGIC GRADE: MODERATE TO POORLY DIFFERENTIATED
EXTENT OF INVASION: CONFINED TO LUNG WITH METASTASIS
EXTENTION TO PLEURA/OTHER STRUCTURES (SPECIFY): NONE
ADDITIONAL PERTINENT FINDINGS - ATELECTASIS, PNEUMONIA, ETC: (SEE NARRATIVE)

MARGINS:

BRONCHIAL: UNINVOLVED
PARENCHYMAL: UNINVOLVED
VASCULAR: UNINVOLVED
OTHER MARGINS (PARIETAL PLEURAL/CHEST WALL, ETC., IF APPLICABLE):
UNINVOLVED
DISTANCE TO PERTINENT MARGIN(S) (AS APPLICABLE): 0.2 CM TO PLEURAL MARGIN

NEOADJUVANT TREATMENT EFFECT (IF APPLICABLE): N/A

[page 5 of 5]
SYNOPTIC REPORT

(Continued)

ARTERIAL (LARGE VESSEL) INVASION: NOT IDENTIFIED

LYMPHATIC INVASION: NOT IDENTIFIED

LYMPH NODE:

f, , , N1 - # INVOLVED/# EXAMINED: 1 OF MULTIPLE

f, , , N2 - # INVOLVED/# EXAMINED: 0 OF MULTIPLE

f, , , N3 - # INVOLVED/# EXAMINED: 0 OF MULTIPLE

OTHER PERTINENT FINDINGS: (SEE NARRATIVE)

pTNM STAGE: pT2b N1 MX

Source: NCI Genomic Data Commons file d23d08cc-20f8-4c67-87da-566f8a0e005e (TCGA-46-6025.1664466D-20AF-4E97-B5E1-A013803F5E6A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).